CCDI case PBBWEK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Adrenal gland.
https://portal.gdc.cancer.gov/cases/5648c4da-09c9-41aa-b6ea-8353eecf1e7b

Demographics
Sex at birth: female.

Diagnoses (1)
1. Adrenal cortical carcinoma: ICD-O-3 morphology code: 8370/3; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 2.1 years (780 days).

Biospecimens (3 samples)
- Sample 0DIPKW: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DIPLG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DIPLW: Tissue type: Tumor; Specimen type: Solid Tissue.
